Gene-level copy-number profile of tumor specimen ALCH-B4DB-TTP1-A from ALCHEMIST case ALCH-B4DB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,780 days).
Specimen ALCH-B4DB-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99686ae6-6494-410e-a9f0-3493003209ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4DB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/73ff8009-1694-4e11-9e83-cf764dda3fc5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 18; copy number 2: 2,390; copy number 3: 3,370; copy number 4: 44,363; copy number 5: 5,925; copy number 6: 2,150; copy number 7: 152; copy number 8: 6; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,155,961, 8 genes (within-gene range 0–3): PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF35P, HNRNPCL2, PRAMEF26.
- chr16:74,305,127–74,335,346, 3 genes (within-gene range 0–4): AC009120.2, AC009120.1, AC009120.3.
- chr18:46,385,707–46,387,083, 1 gene (within-gene range 0–1): AC015959.1.
- chr18:75,070,197–75,074,205, 2 genes: AC015819.2, AC015819.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,744,017–136,758,543, 3 genes, copy number 9 (within-gene range 3–9): LCN6, MIR6722, LCN8.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
